Somatic mutation profile of tumor specimen 1105254 (aliquot 7316UP-1843-1105254) from CPTAC case C760878, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Frontal lobe; Tumor grade: G3.
Specimen 1105254: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d2ba3df-f8a7-45c6-93ae-904c9b9731b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105278 (Blood Derived Normal), aliquot 7316UP-1843-1105278; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6cf81e8-ba20-4d59-8ff8-1de23302c1c1

The open-access MAF lists 86 somatic variants for this specimen: 56 protein-altering or splice-affecting, 21 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 21, Intron 7, Nonsense Mutation 4, Splice Site 3, 5'Flank 1, 5'UTR 1, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 5163/5790 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AFF1 | c.1236_1239del p.H412Qfs*86 | Frame Shift Del (DEL) | VAF 44/141 reads (31%) | catalogued as rs765113099; called by pindel, varscan2
- BIRC6 | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.006); catalogued as rs373105075; called by muse, mutect2, varscan2
- C3 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 204/715 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765821415, COSV55568720; called by muse, mutect2, varscan2
- CFAP20DC | c.1618C>T p.R540* | Nonsense Mutation (SNP) | VAF 40/82 reads (49%) | catalogued as rs952156491; called by mutect2, varscan2
- CIITA | c.3311C>T p.T1104M | Missense Mutation (SNP) | VAF 166/390 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs367805896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP4A22 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 41/116 reads (35%) | catalogued as rs1182232056, COSV53738126; called by muse, mutect2, varscan2
- EDDM3A | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 60/161 reads (37%) | catalogued as rs768794732, COSV58795108, COSV58795417; called by muse, mutect2, varscan2
- FAM53A | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); catalogued as rs559109336, COSV57401825; called by muse, mutect2, varscan2
- FRAS1 | c.4814C>T p.A1605V | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs749776166; called by muse, varscan2
- GABRA6 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 189/454 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751098162, COSV50883531; called by muse, mutect2, varscan2
- GBP3 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 70/186 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs145016759; called by muse, mutect2, varscan2
- HIRA | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs376487965; called by muse, mutect2, varscan2
- HYDIN | c.10129C>T p.R3377C | Missense Mutation (SNP) | VAF 64/201 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as rs779031423, COSV101151299, COSV101157939; called by muse, mutect2, varscan2
- MYCBP2 | c.3329G>T p.W1110L (on ENST00000357337; = p.W1148L on NM_015057.5) | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100629220; called by muse, mutect2
- N4BP2 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as rs780476202, COSV54699826; called by muse, mutect2, varscan2
- NLRP4 | c.554C>G p.T185R | Missense Mutation (SNP) | VAF 69/270 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV56713550; called by muse, mutect2, varscan2
- OR4A15 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 81/190 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs374555766, COSV59036488; called by muse, mutect2, varscan2
- P2RY10 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.581); catalogued as rs769579050, COSV50680628; called by muse, mutect2
- PCDH11Y | c.208G>A p.V70I (on ENST00000400457 / NM_032973.2; = p.V59I on NM_032971.3) | Missense Mutation (SNP) | VAF 208/228 reads (91%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV53082348; called by muse, mutect2, varscan2
- PROKR1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs149410240; called by muse, mutect2, varscan2
- SLC25A21 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 41/103 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs758995590; called by muse, mutect2, varscan2
- SLC6A17 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58991663; called by muse, mutect2, varscan2
- SNX13 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 103/405 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1212626732; called by muse, mutect2, varscan2
- SPOCK3 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 83/261 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs560446612, COSV100692812; called by muse, mutect2, varscan2
- SYT6 | c.746G>A p.R249H (on ENST00000610222 / NM_001366225.1; = p.R164H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 152/403 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as rs139165674, COSV101059648; called by muse, mutect2, varscan2
- TLR2 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 47/139 reads (34%) | catalogued as rs989773958, COSV52607172; called by muse, mutect2, varscan2
- TRPC6 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1437212772; called by muse, mutect2, varscan2
- ZNF407 | c.5666C>T p.T1889M | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs553117551, COSV55254908; called by muse, mutect2, varscan2
- AKAP13 | c.4582G>C p.A1528P | Missense Mutation (SNP) | VAF 101/230 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- ALPP | c.338A>G p.D113G | Missense Mutation (SNP) | VAF 91/197 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANO3 | c.2764-1G>A p.X922_splice | Splice Site (SNP) | VAF 77/177 reads (44%) | called by muse, mutect2, varscan2
- ATP1B1 | c.101A>T p.K34M | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRIP1 | c.3398C>A p.T1133K | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- IGBP1P2 | c.370G>C p.A124P | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- IGKV1D-42 | c.185C>G p.P62R | Missense Mutation (SNP) | VAF 83/209 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ITPKA | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 92/272 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- LAMA1 | c.2572T>G p.S858A | Missense Mutation (SNP) | VAF 143/295 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.185); called by muse, varscan2
- LRRC8B | c.1531A>T p.N511Y | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- MLLT10 | c.603+1G>A p.X201_splice | Splice Site (SNP) | VAF 47/51 reads (92%) | called by muse, mutect2, varscan2
- MTA3 | c.1657A>G p.S553G (on ENST00000405094 / NM_001330442.2; = p.S496G on NM_001282755.1) | Missense Mutation (SNP) | VAF 101/239 reads (42%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- OR4F17 | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 174/1240 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRKCH | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 65/130 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- QKI | c.521_523del p.E174del | In Frame Del (DEL) | VAF 26/64 reads (41%) | called by pindel, varscan2
- QRICH2 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 138/353 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- SEC24D | c.442T>G p.S148A | Missense Mutation (SNP) | VAF 106/214 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINB2 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A1 | c.715-1G>A p.X239_splice | Splice Site (SNP) | VAF 51/102 reads (50%) | called by muse, mutect2, varscan2
- TAT | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 181/434 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEP1 | c.1015G>T p.V339L | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TMEM165 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TPST1 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 130/475 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- VPS18 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.78); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- YWHAZ | c.389_390insAACGTTACTTGGC p.E131Tfs*5 | Frame Shift Ins (INS) | VAF 36/116 reads (31%) | called by mutect2, varscan2
- ZMIZ1 | c.2822C>G p.P941R | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- ZNF229 | c.1598T>C p.L533P | Missense Mutation (SNP) | VAF 96/292 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- AP3B1 | c.1983C>T p.T661= | Silent (SNP) | VAF 110/284 reads (39%) | called by muse, mutect2, varscan2
- CAVIN1 | c.972C>T p.H324= | Silent (SNP) | VAF 125/284 reads (44%) | catalogued as rs1421562805, COSV100824606; called by muse, mutect2, varscan2
- CBFA2T3 | c.1887C>T p.S629= | Silent (SNP) | VAF 46/118 reads (39%) | catalogued as rs750626340; called by muse, mutect2, varscan2
- CYP4Z1 | c.699C>T p.N233= | Silent (SNP) | VAF 32/155 reads (21%) | catalogued as rs370015142; called by muse, mutect2, varscan2
- DPP10 | c.192G>A p.S64= | Silent (SNP) | VAF 57/139 reads (41%) | catalogued as rs201248540; called by muse, mutect2, varscan2
- FLNB | c.6114G>A p.A2038= | Silent (SNP) | VAF 163/362 reads (45%) | catalogued as rs1559730956; called by muse, mutect2, varscan2
- HMGCS2 | c.879C>T p.D293= | Silent (SNP) | VAF 104/234 reads (44%) | catalogued as rs761787433, COSV65569426; called by muse, mutect2, varscan2
- HTR1E | c.105C>G p.L35= | Silent (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- MYLK3 | c.603G>A p.A201= | Silent (SNP) | VAF 30/56 reads (54%) | catalogued as rs781406736; called by muse, varscan2
- OR52J3 | c.654G>A p.S218= | Silent (SNP) | VAF 91/179 reads (51%) | catalogued as rs148600962, COSV66747742; called by muse, mutect2, varscan2
- OR8A1 | c.411T>C p.S137= | Silent (SNP) | VAF 82/154 reads (53%) | catalogued as rs538622740; called by muse, mutect2, varscan2
- POTEJ | c.2622C>T p.D874= | Silent (SNP) | VAF 222/690 reads (32%) | called by muse, varscan2
- PRDM9 | c.2671A>C p.R891= | Silent (SNP) | VAF 144/348 reads (41%) | called by muse, mutect2, varscan2
- PRRC2A | c.411C>T p.S137= | Silent (SNP) | VAF 89/208 reads (43%) | catalogued as rs761009382, COSV63224694; called by muse, mutect2, varscan2
- PYGB | c.156C>T p.Y52= | Silent (SNP) | VAF 94/365 reads (26%) | catalogued as rs1485964440; called by muse, mutect2, varscan2
- SEC14L5 | c.327C>T p.N109= | Silent (SNP) | VAF 48/103 reads (47%) | catalogued as rs375401992; called by muse, mutect2, varscan2
- SERHL2 | c.12C>T p.N4= | Silent (SNP) | VAF 85/323 reads (26%) | called by muse, mutect2, varscan2
- SLCO4A1 | c.891G>A p.T297= | Silent (SNP) | VAF 77/269 reads (29%) | catalogued as rs143407772, COSV53889042; called by muse, mutect2, varscan2
- TMCC2 | c.402C>T p.Y134= | Silent (SNP) | VAF 173/385 reads (45%) | catalogued as rs77588763, COSV58005035; called by muse, mutect2, varscan2
- TMEM270 | c.678C>T p.A226= | Silent (SNP) | VAF 166/563 reads (29%) | catalogued as rs201571768; called by muse, mutect2, varscan2
- TPTE2 | c.213A>T p.V71= | Silent (SNP) | VAF 46/74 reads (62%) | called by muse, mutect2, varscan2
- ACADM | chr1:75724665 C>T | 5'Flank (SNP) | VAF 11/25 reads (44%) | catalogued as rs1307548224; called by muse, mutect2, varscan2
- ENY2 | c.230-678C>T | Intron (SNP) | VAF 102/238 reads (43%) | called by muse, mutect2, varscan2
- FCRL5 | c.-21C>G | 5'UTR (SNP) | VAF 95/240 reads (40%) | called by muse, mutect2, varscan2
- HTN3 | c.73-34A>C | Intron (SNP) | VAF 54/119 reads (45%) | catalogued as COSV66879574; called by muse, mutect2, varscan2
- MYO10 | c.21+19724G>A | Intron (SNP) | VAF 92/283 reads (33%) | catalogued as rs772652920, COSV72454035; called by muse, mutect2, varscan2
- SNRNP200 | c.5754+39C>G | Intron (SNP) | VAF 152/340 reads (45%) | catalogued as rs746692485; called by muse, mutect2, varscan2
- TSPEAR | c.633+33G>A | Intron (SNP) | VAF 170/423 reads (40%) | catalogued as rs777838829; called by muse, mutect2, varscan2
- TTN | c.10360+1582G>A | Intron (SNP) | VAF 57/122 reads (47%) | called by muse, mutect2, varscan2
- ZNF497 | c.-111-646C>T | Intron (SNP) | VAF 36/227 reads (16%) | catalogued as rs894474633; called by muse, mutect2, varscan2
